Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JB-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

Patient ID

(A) LEFT INGUINAL CONTENTS:

METASTATIC MELANOMA TO TWO OF FOUR LYMPH NODES (2/4).
LARGEST TUMOR (65.0 X 16.0 MM), WITH EXTRACAPSULAR EXTENSION.

(B) ADDITIONAL APEX OF FEMORAL TRIANGLE:

MELANOMA METASTATIC TO SOFT TISSUE (50.0 X 15.0 MM).
TUMOR IS FOCALLY PRESENT AT ONE PERIPHERAL MARGIN.

(C) LEFT COMMON ILIAC BIFURCATION:

One lymph node, negative for melanoma (0/1).

(D) LEFT ILIAC AND OBTURATOR NODES:

Twelve lymph nodes, negative for melanoma (0/12).
Focal pigmented macrophages.

1CB-0-3

Melanoma, Nos 8720/3
Site: lymph node, inguinal

C77.4

hw 7/24/11

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) LEFT INGUINAL CONTENTS - A 15 x 10 x 7.0 cm portion of soft tissue with two tan-brown tumor nodules (2.5 x 2.0 x 1.5 cm and 6.5 x 6.0 x 3.5 cm) possibly composed of matted lymph nodes are present. Three additional lymph nodes (0.6 x 0.5 x 0.4 cm, 1.0 x 0.6 x 0.5 cm) are also identified. Lymph nodes appear to be grossly involved by tumor.

Portions of the tumor are submitted to the tumor bank.

SECTION CODE: A1-A6, larger nodule, representative section; A7-A9, smaller nodule, representative section; A10, one lymph node; A11, two lymph nodes.

(B) ADDITIONAL APEX OF FEMORAL TRIANGLE - Received are skin and underlying soft tissue, 5.0 x 1.5 x 2.0 cm. The skin surface is unremarkable. The cut surface inked blue. The specimen is serially sectioned. A well-defined black nodule, 1.2 x 1.0 x 1.0 cm is identified, and the nodule expanded to one side margin.

SECTION CODE: B1, both tips; B2-B5, nodule serially sectioned and entirely submitted.

(C) LEFT COMMON ILIAC BIFURCATION - One lymph node is identified, 0.5 x 0.3 x 0.3 cm, and entirely submitted in C.

(D) LEFT ILIAC AND OBTURATOR CONTENTS - Adipose tissue (4.0 x 2.5 x 1.5 cm). Thirteen lymph nodes are identified, ranging from 0.2 x 0.2 x 0.2 cm to 1.6 x 0.8 x 0.7 cm.

SECTION CODE: D1, five lymph nodes; D2, three lymph nodes; D3, three lymph nodes; D4, one lymph node serially sectioned; D5, one lymph node serially sectioned.

CLINICAL HISTORY

None given.

[page 2 of 2]
SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 6408f6d0-afb2-4052-b014-9bb960dac6a3 (TCGA-D3-A2JB.3678202C-DFD7-4D37-AA08-3C2C63001AB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).